Somatic mutation profile of tumor specimen 0DSR4Z from CCDI case PBCIKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dermatofibrosarcoma protuberans, NOS; Tissue or organ of origin: Skin of lower limb and hip; Age at diagnosis: 15.0 years (5,476 days).
Specimen 0DSR4Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1af91b5-c03a-4104-86d7-7cadb12d551c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSR5A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18cf33b3-222c-48ed-927f-6f0a79cdaff7

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1554342786; called by pindel, varscan2
- POTEH | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs762153495, COSV58887242; called by muse, mutect2
- EPM2A | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GJA5 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 44/602 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
